Somatic mutation profile of tumor specimen TCGA-CV-7418-01A (aliquot TCGA-CV-7418-01A-11D-2078-08) from TCGA case TCGA-CV-7418, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-CV-7418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2273e2f5-1efb-490f-9d0e-e7c56259435f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7418-10A (Blood Derived Normal), aliquot TCGA-CV-7418-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17cc538d-64b4-49ff-8aba-0131f545f1af

The open-access MAF lists 168 somatic variants for this specimen: 126 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 40, Frame Shift Ins 4, Splice Site 4, Frame Shift Del 4, Nonsense Mutation 4, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGA | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909606, CM100506, CM930249, COSV57393361; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 41/60 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ACIN1 | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.405); catalogued as rs945209622, COSV99400556; called by muse, mutect2, varscan2
- ADAM32 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101165540; called by muse, mutect2, varscan2
- ADCY1 | c.1226T>A p.L409Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99813155; called by muse, mutect2, varscan2
- ADGRF4 | c.1634G>C p.R545T | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99349217; called by muse, mutect2, varscan2
- ADPGK | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61173412; called by muse, mutect2, varscan2
- AHCYL2 | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100273845; called by muse, mutect2, varscan2
- ANKFY1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as rs147745463, COSV100492449; called by muse, mutect2, varscan2
- ARHGEF26 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV100726717; called by muse, mutect2, varscan2
- ASPM | c.3706C>A p.H1236N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99661366; called by muse, mutect2, varscan2
- BTBD3 | c.938T>A p.L313Q | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99656253; called by muse, mutect2, varscan2
- C12orf4 | c.921T>A p.S307R | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99713026; called by muse, mutect2, varscan2
- C5 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56332372, COSV99799073; called by muse, mutect2, varscan2
- CACNB1 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100703661; called by muse, mutect2, varscan2
- CC2D2B | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100729601; called by muse, mutect2, varscan2
- CD248 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV100256842; called by muse, varscan2
- CD248 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100256847; called by muse, varscan2
- CD248 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100256565, COSV100256854; called by muse, mutect2, varscan2
- CD248 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs746807760, COSV100256857; called by muse, mutect2
- CD248 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100256858; called by muse, varscan2
- CD248 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as rs371429917; called by muse, varscan2
- CFAP46 | c.6722A>G p.D2241G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99585834; called by muse, mutect2, varscan2
- CHAF1A | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100011599; called by muse, mutect2, varscan2
- CIT | c.5847C>A p.H1949Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV99951471; called by muse, mutect2
- COL16A1 | c.2837C>G p.P946R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV99595867; called by muse, mutect2, varscan2
- COL6A6 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV100651130; called by muse, mutect2, varscan2
- COPB2 | c.895-1G>T p.X299_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100300987; called by muse, mutect2, varscan2
- COPZ1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs781082088, COSV100017732; called by muse, mutect2
- CSMD3 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); catalogued as COSV99852076; called by muse, mutect2, varscan2
- CUL3 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52366295, COSV52371086; called by muse, mutect2, varscan2
- CYP8B1 | c.133C>A p.H45N | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV100296376; called by muse, mutect2, varscan2
- DDX49 | c.941T>A p.I314N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99651306; called by muse, mutect2, varscan2
- DNAAF2 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100024255, COSV100024276; called by muse, mutect2, varscan2
- DNAAF2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); catalogued as rs1217877304, COSV100024277; called by muse, mutect2, varscan2
- DPYS | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100680301; called by muse, mutect2, varscan2
- ERCC6L | c.2452T>G p.F818V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV57822577; called by muse, mutect2, varscan2
- ESCO2 | c.1670T>G p.L557R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100533467; called by muse, mutect2, varscan2
- EXD2 | c.1293-2A>G p.X431_splice (on ENST00000312994 / NM_001193362.1; = p.X306_splice on NM_018199.3) | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100474653; called by muse, mutect2, varscan2
- FAM214B | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100521500; called by muse, mutect2, varscan2
- FBXO21 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100401911; called by muse, mutect2, varscan2
- FILIP1L | c.1250T>G p.V417G (on ENST00000354552 / NM_182909.3; = p.V177G on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100497471; called by muse, mutect2, varscan2
- FUT2 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs1289258173, COSV101218174; called by muse, mutect2, varscan2
- GJA1 | c.639G>T p.M213I | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV99247409; called by muse, mutect2, varscan2
- GLRA1 | c.1291T>G p.F431V (on ENST00000455880 / NM_001146040.2; = p.F423V on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99199744; called by muse, mutect2, varscan2
- GOLIM4 | c.1279C>G p.L427V | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV100463662; called by muse, mutect2, varscan2
- HACD4 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101529970, COSV72136707; called by muse, mutect2, varscan2
- HAPLN4 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as rs778025794, COSV99363959; called by muse, mutect2, varscan2
- HECTD1 | c.1907A>C p.N636T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV101237591; called by muse, mutect2, varscan2
- HERC2 | c.11294C>T p.A3765V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV99877750; called by muse, mutect2, varscan2
- ICE1 | c.2314A>G p.I772V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99666090; called by muse, mutect2, varscan2
- IL20RB | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV100291326, COSV59048591; called by muse, mutect2, varscan2
- KATNIP | c.3553-1G>A p.X1185_splice | Splice Site (SNP) | VAF 36/67 reads (54%) | catalogued as rs1372332178, COSV99852310; called by muse, mutect2, varscan2
- KCNH7 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59790686, COSV59813296; called by muse, mutect2
- KCNJ11 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs751424820, COSV56856601; called by muse, mutect2, varscan2
- KCNQ3 | c.2498T>A p.L833H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101196624; called by muse, mutect2, varscan2
- KIF5C | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101276165, COSV101276235; called by muse, mutect2, varscan2
- KLHL10 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.446); catalogued as rs781939002, COSV53174197; called by muse, mutect2, varscan2
- KLHL14 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV100809396; called by muse, mutect2, varscan2
- KLHL24 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs529830658, COSV99665237; called by muse, mutect2, varscan2
- KRTAP5-8 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 77/595 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV101273178, COSV68324821; called by muse, mutect2, varscan2
- KSR2 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs374020752; called by muse, mutect2, varscan2
- LAMA4 | c.1402C>G p.R468G (on ENST00000230538 / NM_001105206.3; = p.R461G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as rs781834628, COSV100039891; called by muse, mutect2, varscan2
- LCOR | c.4190G>A p.S1397N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99617314; called by muse, mutect2, varscan2
- LPAR4 | c.814T>G p.Y272D | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101425184, COSV70912548; called by muse, mutect2, varscan2
- MICB | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as COSV99357639; called by muse, mutect2, varscan2
- MYH10 | c.5343G>T p.Q1781H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99346695; called by muse, mutect2, varscan2
- NBPF9 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs1385981328; called by muse, mutect2
- NUTM2G | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as COSV100673009; called by mutect2, varscan2
- ODF3 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285380; called by muse, varscan2
- OR2T1 | c.128T>A p.V43D | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100822373; called by muse, mutect2, varscan2
- OTOGL | c.6043G>T p.V2015F (on ENST00000547103; = p.V2006F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100088125, COSV54014310; called by muse, mutect2, varscan2
- PARP11 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as rs375575295, COSV57394330; called by muse, mutect2, varscan2
- PCDHA2 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974208; called by muse, mutect2, varscan2
- PCDHA3 | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV100793866, COSV63545938; called by muse, mutect2, varscan2
- PCNT | c.7072C>G p.P2358A | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100856215; called by muse, mutect2, varscan2
- PCNX4 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV100471026; called by muse, mutect2, varscan2
- PDZD8 | c.1916T>C p.V639A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as COSV100559687; called by muse, mutect2
- PGLYRP2 | c.349T>A p.S117T | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.621); catalogued as COSV99484382; called by muse, mutect2, varscan2
- PIGS | c.1241C>G p.T414R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs755566243, COSV99257385; called by muse, mutect2, varscan2
- PIP5K1B | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 167/224 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99600109; called by muse, mutect2, varscan2
- PKHD1L1 | c.8725A>G p.I2909V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV101007176; called by muse, mutect2, varscan2
- PLAAT2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as rs1291172665, COSV99738286; called by muse, mutect2, varscan2
- PRKAR2B | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55926905; called by muse, mutect2, varscan2
- PRSS48 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs767496040, COSV71613603; called by muse, mutect2, varscan2
- PSMB5 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as COSV100557434; called by muse, mutect2, varscan2
- RIPK4 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205469, COSV60185852; called by muse, mutect2, varscan2
- RXYLT1 | c.972G>C p.Q324H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99707153; called by muse, mutect2, varscan2
- SEL1L | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.394); catalogued as COSV100378197; called by muse, mutect2, varscan2
- SEL1L | c.789T>A p.F263L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV100378199; called by muse, mutect2, varscan2
- SHTN1 | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.073); catalogued as COSV99599590; called by muse, mutect2, varscan2
- SLC27A6 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99323717; called by muse, mutect2, varscan2
- SLC30A4 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99970505; called by muse, mutect2, varscan2
- SLC35F4 | c.1069G>T p.A357S (on ENST00000339762 / NM_001352015.2; = p.A321S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100334360; called by muse, mutect2, varscan2
- SLC40A1 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751270910, COSV53722202; called by muse, mutect2, varscan2
- SNX33 | c.742A>G p.S248G | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100145920; called by muse, mutect2
- SORCS3 | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs748113325, COSV100863944; called by muse, mutect2, varscan2
- SRRM1 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV100105326, COSV60482103; called by muse, mutect2, varscan2
- SULF1 | c.1295C>G p.S432* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99484698; called by muse, mutect2, varscan2
- TBCK | c.998G>C p.G333A (on ENST00000273980 / NM_001163436.4; = p.G270A on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99913372; called by muse, mutect2, varscan2
- THSD7B | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99759694; called by muse, mutect2, varscan2
- TM9SF3 | c.1225C>G p.L409V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100951900; called by muse, mutect2, varscan2
- TMCC2 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100405711, COSV100405812; called by muse, mutect2, varscan2
- TMEM135 | c.699A>G p.I233M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs568746924, COSV100450377; called by muse, varscan2
- TNNI2 | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99425676; called by muse, mutect2, varscan2
- TRMT10C | c.290T>G p.F97C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99998426; called by muse, mutect2, varscan2
- UBE3B | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV99784630; called by muse, mutect2, varscan2
- UBR2 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100867584; called by muse, mutect2, varscan2
- UNC45A | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs549730654, COSV57746211; called by muse, mutect2, varscan2
- ZC3H11A | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100142974; called by muse, mutect2, varscan2
- ZFC3H1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated, low confidence (0.52); PolyPhen possibly damaging (0.528); catalogued as rs757892160, COSV100350637; called by muse, mutect2, varscan2
- ZMAT4 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99911708; called by muse, mutect2, varscan2
- ZNF521 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833663; called by muse, mutect2, varscan2
- ZNF750 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99490032; called by muse, mutect2, varscan2
- ZNF804A | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100170850; called by muse, mutect2, varscan2
- ZRANB3 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV99925200; called by muse, mutect2, varscan2
- APC | c.2390del p.G797Vfs*23 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by pindel, varscan2
- CAPN6 | c.1641_1646del p.E548_E549del | In Frame Del (DEL) | VAF 21/42 reads (50%) | called by mutect2, pindel, varscan2
- EHBP1 | c.853_860dup p.E288Tfs*36 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- FTL | c.397_400del p.H133Sfs*2 | Frame Shift Del (DEL) | VAF 49/199 reads (25%) | called by mutect2, pindel, varscan2
- GAB1 | c.1353dup p.P452Sfs*30 | Frame Shift Ins (INS) | VAF 32/74 reads (43%) | called by mutect2, pindel, varscan2
- HAPLN3 | c.390_391del p.L131Gfs*16 | Frame Shift Del (DEL) | VAF 28/160 reads (18%) | called by pindel, varscan2
- PCDHGB5 | c.1567A>T p.T523S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYNRG | c.3647dup p.M1216Ifs*10 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- TBL1Y | c.960dup p.A321Rfs*3 | Frame Shift Ins (INS) | VAF 32/57 reads (56%) | called by mutect2, pindel, varscan2
- TGM7 | c.731del p.G244Afs*31 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- BRSK1 | c.636A>C p.A212= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100511126; called by muse, mutect2, varscan2
- CD248 | c.654G>A p.E218= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV100256856; called by muse, mutect2
- CDH2 | c.582G>T p.R194= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs752832492, COSV52287675, COSV99299072; called by muse, mutect2, varscan2
- CELSR3 | c.3927C>T p.D1309= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99375484; called by muse, mutect2, varscan2
- CEP250 | c.4549C>A p.R1517= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100699252; called by muse, mutect2, varscan2
- COL12A1 | c.4896C>T p.V1632= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as COSV100486861; called by muse, mutect2, varscan2
- CST9L | c.411C>G p.L137= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs1332426645, COSV100980927; called by muse, mutect2, varscan2
- CYC1 | c.546T>C p.S182= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV59645112; called by muse, mutect2, varscan2
- GRB7 | c.501G>T p.V167= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV100485686; called by muse, mutect2
- HELZ | c.651A>C p.S217= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1487452752, COSV100699153; called by muse, mutect2, varscan2
- HS1BP3 | c.990C>A p.P330= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV100398143; called by muse, varscan2
- HSPA8 | c.654G>A p.E218= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99914723; called by muse, mutect2, varscan2
- HSPH1 | c.2385A>G p.T795= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs749769750, COSV100185255; called by muse, mutect2, varscan2
- LHX5 | c.570G>A p.K190= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1230453393, COSV99922592; called by muse, mutect2, varscan2
- LRP2 | c.13644T>C p.D4548= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs1382873079, COSV99790864; called by muse, mutect2, varscan2
- MICU1 | c.900G>A p.Q300= (on ENST00000361114 / NM_001195518.2; = p.Q306= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV63145604; called by muse, mutect2
- MLNR | c.1131G>A p.P377= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as COSV54534072; called by muse, mutect2, varscan2
- MNT | c.1491C>G p.T497= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99438427; called by muse, mutect2
- MUC6 | c.3240C>A p.P1080= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101424898; called by muse, mutect2
- MYH9 | c.2184C>A p.S728= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99340106; called by muse, mutect2, varscan2
- NDUFA6 | c.288A>G p.V96= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as rs878997515, COSV100515685; called by muse, mutect2, varscan2
- NID1 | c.819C>T p.G273= | Silent (SNP) | VAF 69/251 reads (27%) | catalogued as rs781640098, COSV51620191; called by muse, mutect2
- NUTM2G | c.675C>G p.P225= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as COSV100673011; called by muse, mutect2, varscan2
- OR2M3 | c.885G>A p.K295= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV71758945; called by muse, mutect2, varscan2
- OR7E24 | c.270T>G p.G90= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV101509703; called by muse, mutect2, varscan2
- OTOP2 | c.1608C>T p.I536= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs747645057, COSV100173148; called by muse, mutect2, varscan2
- OTUD5 | c.1581C>A p.S527= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV99332361; called by muse, mutect2, varscan2
- PARP12 | c.1518C>A p.S506= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99694351; called by muse, mutect2, varscan2
- PDCD11 | c.1317T>C p.I439= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100874446; called by muse, mutect2, varscan2
- PLEKHM2 | c.477C>T p.Y159= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV101009232; called by muse, mutect2, varscan2
- SDHAF3 | c.78C>T p.D26= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100836557; called by muse, mutect2, varscan2
- SIX4 | c.1707G>A p.Q569= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs564205527, COSV99382596; called by muse, mutect2, varscan2
- SLC25A45 | c.633A>T p.A211= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as COSV99587453; called by muse, mutect2, varscan2
- SLC33A1 | c.1095A>G p.K365= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100848371; called by muse, mutect2, varscan2
- SLC6A4 | c.1392G>A p.R464= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99911664; called by muse, mutect2, varscan2
- SNX4 | c.1134A>G p.L378= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV52538739; called by muse, mutect2, varscan2
- WASHC5 | c.2241C>T p.T747= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100573177; called by muse, mutect2, varscan2
- WNT8A | c.690C>T p.S230= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs761534255, COSV100843121; called by muse, mutect2, varscan2
- ZMIZ2 | c.1287T>C p.D429= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as rs1329405799, COSV99537358; called by muse, mutect2
- ZNF394 | c.849T>C p.N283= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as rs1363903558, COSV100530003; called by muse, mutect2
- DST-AS1 | n.139+7532C>A | Intron (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100880213; called by muse, mutect2, varscan2
- TTN | c.34264+591C>T | Intron (SNP) | VAF 63/179 reads (35%) | catalogued as COSV100636156; called by muse, mutect2, varscan2
